Somatic mutation profile of tumor specimen MP2PRT-PARMHC-TMP1-A (aliquot MP2PRT-PARMHC-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARMHC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 7.1 years (2,595 days).
Specimen MP2PRT-PARMHC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40f8c7ac-b0f2-4a8e-ba86-cea0021aba18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMHC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMHC-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7306487-0ff7-4843-b5e0-38f925394397

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 161/401 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs1404359662, COSV59194465; called by muse, mutect2, varscan2
- EEF2 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 251/591 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58579201; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200254775, COSV100437966; called by muse, mutect2, varscan2
- CPEB2 | c.315_316insCGG p.P105_A106insR | In Frame Ins (INS) | VAF 307/683 reads (45%) | called by mutect2, pindel, varscan2
- PRAG1 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 319/744 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
